Gene-level copy-number profile of tumor specimen ALCH-AEYX-TTP1-A from ALCHEMIST case ALCH-AEYX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.1 years (26,697 days).
Specimen ALCH-AEYX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3c2553e3-84fd-45c2-8615-bd916e638078.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEYX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/847c682d-f0b7-4b8c-a16c-7491b9953188

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,903; copy number 2: 54,005; copy number 3: 1,895; copy number 4: 73; copy number 5: 29; copy number 6: 13.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,578,473–128,564,679, 16 genes, copy number 5–6: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:129,241,228–129,291,275, 3 genes, copy number 5: AC103833.2, AC103833.1, RN7SKP206.
- chr8:141,117,278–142,209,003, 23 genes, copy number 5: DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
